Somatic mutation profile of tumor specimen TCGA-2G-AAFO-01A (aliquot TCGA-2G-AAFO-01A-31D-A42Y-10) from TCGA case TCGA-2G-AAFO, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 33.7 years (12,298 days).
Specimen TCGA-2G-AAFO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a10cecbb-c9c2-4b7c-a25d-2c01b3df2714.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAFO-10A (Blood Derived Normal), aliquot TCGA-2G-AAFO-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8661544-2652-4221-a980-192ba73eb99d

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Nonsense Mutation 2, Silent 1, Splice Region 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPS8 | c.1294C>T p.R432* | Nonsense Mutation (SNP) | VAF 25/463 reads (5%) | catalogued as rs1027436562; called by muse, mutect2
- PHF21B | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | catalogued as COSV57558991; called by muse, mutect2, varscan2
- TRAM1L1 | c.214C>T p.L72F | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.029); catalogued as rs1025102777; called by muse, mutect2, varscan2
- EDDM3B | c.160A>G p.M54V | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HNRNPA1 | c.677-3C>T | Splice Region (SNP) | VAF 7/55 reads (13%) | called by muse, mutect2, varscan2
- INSYN2B | c.1232A>T p.D411V | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- QSER1 | c.2774A>G p.Q925R (on ENST00000399302; = p.Q1054R on NM_001076786.3) | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RPH3AL | c.149_151dup p.A50dup | In Frame Ins (INS) | VAF 6/56 reads (11%) | called by mutect2, pindel
- SACS | c.8962G>T p.D2988Y | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- SCCPDH | c.1058A>T p.K353M | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- ZRANB1 | c.650C>G p.P217R | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- DNAH14 | c.7956G>A p.E2652= (on ENST00000445597; = p.E3455= on NM_001367479.1) | Silent (SNP) | VAF 70/268 reads (26%) | called by muse, mutect2, varscan2
